Somatic mutation profile of tumor specimen ALCH-B256-TTP1-A (aliquot ALCH-B256-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B256, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 68.6 years (25,059 days).
Specimen ALCH-B256-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4dc01d9-64d6-4b5b-b061-7c9625bfd8d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B256-NB1-A (Blood Derived Normal), aliquot ALCH-B256-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7d2b83e-fefa-4f22-9f29-50a89dd4f950

The open-access MAF lists 614 somatic variants for this specimen: 396 protein-altering or splice-affecting, 116 silent, 102 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 341, Silent 116, Intron 44, RNA 25, Nonsense Mutation 24, 5'UTR 14, Frame Shift Del 12, 3'UTR 9, Splice Site 9, 5'Flank 7, Splice Region 6, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CB | c.3151G>A p.E1051K | Missense Mutation (SNP) | VAF 414/544 reads (76%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV56683948; called by muse, varscan2
- TP53 | c.542G>C p.R181P | Missense Mutation (SNP) | VAF 267/353 reads (76%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as CM056067, CM920671, CM942120, COSV52675795, COSV52676870, COSV52730435, COSV53567603; called by muse, mutect2, varscan2
- AFM | c.1123C>G p.Q375E | Missense Mutation (SNP) | VAF 65/184 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV99888573; called by muse, mutect2, varscan2
- AK5 | c.770G>T p.R257L (on ENST00000354567 / NM_174858.3; = p.R231L on NM_012093.4) | Missense Mutation (SNP) | VAF 103/355 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60971016; called by muse, mutect2, varscan2
- ALPK2 | c.5125G>C p.E1709Q | Missense Mutation (SNP) | VAF 123/195 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as COSV64492775; called by muse, mutect2, varscan2
- AMER3 | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 96/154 reads (62%) | catalogued as COSV100366716; called by muse, mutect2, varscan2
- ANAPC10 | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 83/239 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.021); catalogued as rs778469780; called by muse, mutect2, varscan2
- ANO4 | c.338G>C p.R113P (on ENST00000392977 / NM_001286615.2; = p.R78P on NM_178826.4) | Missense Mutation (SNP) | VAF 99/308 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV100152777, COSV54606721; called by muse, mutect2, varscan2
- ARX | c.1621G>T p.E541* | Nonsense Mutation (SNP) | VAF 104/297 reads (35%) | catalogued as COSV66875219; called by muse, mutect2, varscan2
- BMP3 | c.69G>C p.E23D | Missense Mutation (SNP) | VAF 92/226 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1174760853, COSV99261367; called by muse, mutect2, varscan2
- BRCA1 | c.4418C>G p.S1473C | Missense Mutation (SNP) | VAF 121/213 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.43); catalogued as COSV100523135, COSV58790529; called by muse, mutect2, varscan2
- BRIP1 | c.1186C>G p.H396D | Missense Mutation (SNP) | VAF 57/86 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM135043; called by muse, mutect2, varscan2
- C1orf105 | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 89/224 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV62959741; called by muse, mutect2, varscan2
- CACNA2D3 | c.1127A>G p.Y376C | Missense Mutation (SNP) | VAF 66/114 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1303530299; called by muse, mutect2, varscan2
- CATSPER1 | c.1422C>G p.I474M | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV56412701; called by muse, mutect2, varscan2
- CDH7 | c.433G>C p.D145H | Missense Mutation (SNP) | VAF 130/227 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59884653; called by muse, mutect2, varscan2
- CELF3 | c.966C>A p.Y322* | Nonsense Mutation (SNP) | VAF 109/310 reads (35%) | catalogued as COSV51885165, COSV51886448; called by muse, mutect2, varscan2
- CEP170B | c.1157G>A p.R386Q (on ENST00000453495; = p.R315Q on NM_015005.3) | Missense Mutation (SNP) | VAF 149/861 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); catalogued as rs376478179; called by muse, mutect2, varscan2
- CHM | c.519A>T p.E173D | Missense Mutation (SNP) | VAF 41/337 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs1382467511; called by muse, mutect2, varscan2
- CMYA5 | c.1805A>G p.Q602R | Missense Mutation (SNP) | VAF 115/195 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs753816970; called by muse, mutect2, varscan2
- CNBD2 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 97/249 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs750702259, COSV62586269; called by muse, mutect2, varscan2
- CNGA2 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 70/259 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV61705157; called by muse, mutect2, varscan2
- COL25A1 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67646942; called by muse, mutect2, varscan2
- CREG2 | c.535G>T p.D179Y | Missense Mutation (SNP) | VAF 139/338 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759112720; called by muse, mutect2, varscan2
- CRYBG3 | c.7858C>T p.Q2620* | Nonsense Mutation (SNP) | VAF 89/120 reads (74%) | catalogued as rs755121332; called by muse, mutect2, varscan2
- CRYM | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 113/184 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1156965560; called by muse, mutect2, varscan2
- CSMD1 | c.3307G>T p.A1103S (on ENST00000520002; = p.A1102S on NM_033225.6) | Missense Mutation (SNP) | VAF 51/89 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100149331, COSV99064816; called by muse, mutect2, varscan2
- CTH | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 98/338 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100697086, COSV61009801; called by muse, mutect2, varscan2
- CTNND2 | c.2029G>T p.D677Y | Missense Mutation (SNP) | VAF 87/164 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs966178877, COSV100476841; called by muse, mutect2, varscan2
- CUL5 | c.1637C>T p.S546L | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101263729; called by muse, mutect2, varscan2
- DACH1 | c.1936G>T p.E646* (on ENST00000619232 / NM_001366712.1; = p.E392* on NM_004392.6) | Nonsense Mutation (SNP) | VAF 62/254 reads (24%) | catalogued as COSV57503001; called by muse, varscan2
- DGCR8 | c.1990G>C p.G664R | Missense Mutation (SNP) | VAF 71/185 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV61227958; called by muse, mutect2, varscan2
- DMD | c.10465C>G p.R3489G | Missense Mutation (SNP) | VAF 98/290 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV100625868; called by muse, mutect2, varscan2
- DNAH2 | c.4291C>T p.R1431C | Missense Mutation (SNP) | VAF 123/327 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs777742686, COSV101209662; called by muse, mutect2, varscan2
- DNTTIP2 | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 156/437 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV100785212; called by muse, mutect2, varscan2
- EBF2 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 130/226 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101282234; called by muse, mutect2, varscan2
- EHF | c.878G>C p.R293P | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV57670746; called by muse, mutect2, varscan2
- EID1 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.365); catalogued as rs1567059850; called by muse, mutect2, varscan2
- EPHA7 | c.2214G>T p.M738I | Missense Mutation (SNP) | VAF 86/308 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.723); catalogued as COSV65193844; called by muse, mutect2, varscan2
- ESRRB | c.1075G>T p.D359Y | Missense Mutation (SNP) | VAF 119/337 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs765737772; called by muse, mutect2, varscan2
- ESYT1 | c.2164G>C p.D722H | Missense Mutation (SNP) | VAF 88/292 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239960533; called by muse, mutect2, varscan2
- EYA1 | c.1678G>C p.E560Q | Missense Mutation (SNP) | VAF 134/248 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58159368; called by muse, mutect2, varscan2
- FAM160A1 | c.2596G>C p.E866Q | Missense Mutation (SNP) | VAF 100/240 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.175); catalogued as rs763904764; called by muse, mutect2, varscan2
- FOXC1 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 82/122 reads (67%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1489771788; called by muse, mutect2, varscan2
- FRAS1 | c.2818G>C p.E940Q | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as rs573458782, COSV53642616; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GCAT | c.916G>C p.A306P | Missense Mutation (SNP) | VAF 130/195 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV50649142, COSV50650186; called by muse, mutect2, varscan2
- GHRHR | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 163/464 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.465); catalogued as COSV58195910; called by muse, mutect2, varscan2
- GLI1 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs774058977, COSV57358829; called by muse, mutect2, varscan2
- GUCY1A2 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV56497897; called by muse, mutect2, varscan2
- HAO1 | c.536C>A p.P179Q | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV66492371; called by muse, mutect2, varscan2
- HAVCR1 | c.536_538del p.L179_T180delinsP | In Frame Del (DEL) | VAF 225/583 reads (39%) | catalogued as rs1561599383; called by mutect2, pindel, varscan2
- HFE | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 171/697 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs772818312, CM112342, COSV58512899; called by muse, mutect2, varscan2
- HMCN1 | c.5748T>C p.H1916= | Splice Region (SNP) | VAF 161/303 reads (53%) | catalogued as rs753795619; called by muse, mutect2, varscan2
- IGKV1-12 | c.287C>A p.T96N | Missense Mutation (SNP) | VAF 91/805 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs376599105; called by muse, mutect2, varscan2
- INSRR | c.1517A>G p.Y506C | Missense Mutation (SNP) | VAF 90/329 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV63876647; called by muse, mutect2, varscan2
- ITPR2 | c.3754A>T p.N1252Y | Missense Mutation (SNP) | VAF 88/426 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748386553; called by muse, mutect2, varscan2
- JPH4 | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as rs1292100526; called by muse, mutect2, varscan2
- KCNK4 | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs993080855; called by muse, mutect2, varscan2
- KDM4D | c.977G>C p.R326P | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58635313; called by muse, mutect2, varscan2
- KDR | c.2882G>T p.R961L | Missense Mutation (SNP) | VAF 116/316 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as COSV55769273; called by muse, mutect2, varscan2
- KIAA2012 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 119/196 reads (61%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs747893606; called by muse, mutect2, varscan2
- KLF5 | c.1165C>G p.H389D | Missense Mutation (SNP) | VAF 66/393 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66614500; called by muse, mutect2, varscan2
- KLHL13 | c.1336G>T p.V446F | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99452550; called by muse, mutect2, varscan2
- KMT2A | c.2905C>G p.L969V | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.272); catalogued as rs864309568; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- L1CAM | c.3550G>C p.E1184Q | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1557089371; called by muse, mutect2, varscan2
- LAMA4 | c.1523C>A p.A508D (on ENST00000230538 / NM_001105206.3; = p.A501D on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 236/652 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.197); catalogued as rs1489894322; called by muse, mutect2, varscan2
- MACF1 | c.18878G>C p.G6293A (on ENST00000372915; = p.G4338A on NM_012090.5) | Missense Mutation (SNP) | VAF 243/829 reads (29%) | catalogued as rs567664427; called by muse, mutect2, varscan2
- MAGEE1 | c.2277G>T p.M759I | Missense Mutation (SNP) | VAF 119/424 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.161); catalogued as COSV100819497, COSV63910497; called by muse, mutect2, varscan2
- MAZ | c.58G>C p.D20H | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as rs373977511; called by muse, mutect2, varscan2
- MMP27 | c.391A>G p.I131V | Missense Mutation (SNP) | VAF 133/375 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as rs751085021; called by muse, mutect2, varscan2
- MRC2 | c.3888G>C p.Q1296H | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as COSV100316708; called by muse, mutect2, varscan2
- MROH8 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1368862177; called by muse, mutect2, varscan2
- MUC17 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 263/419 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV60302385; called by muse, mutect2, varscan2
- MYCT1 | c.212C>A p.S71Y | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1291661188; called by muse, mutect2, varscan2
- MYH2 | c.1844C>G p.S615C | Missense Mutation (SNP) | VAF 145/242 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV55441754; called by muse, mutect2, varscan2
- MYO18B | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs751222865, COSV59126310, COSV59129122; called by muse, mutect2, varscan2
- NBAS | c.4208C>T p.S1403L | Missense Mutation (SNP) | VAF 114/291 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs1281256183; called by muse, mutect2, varscan2
- NDN | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs772214524, COSV59361205; called by muse, mutect2, varscan2
- NIPBL | c.5710-1G>C p.X1904_splice | Splice Site (SNP) | VAF 41/146 reads (28%) | catalogued as COSV56948448, COSV99239202; called by muse, mutect2, varscan2
- NLRC4 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61593077; called by muse, mutect2, varscan2
- NRXN3 | c.2184G>T p.R728S (on ENST00000335750 / NM_001330195.2; = p.R355S on NM_004796.6) | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as COSV59808466; called by muse, mutect2, varscan2
- NTN1 | c.173C>A p.A58E | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs530015851; called by muse, mutect2, varscan2
- NTRK3 | c.2484del p.K829Rfs*18 (on ENST00000360948 / NM_001012338.2; = p.K815Rfs*18 on NM_002530.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 98/399 reads (25%) | catalogued as COSV62304362; called by mutect2, pindel*, varscan2
- NXF3 | c.1592C>T p.S531L | Missense Mutation (SNP) | VAF 132/406 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as rs758955368, COSV67702707, COSV67705135; called by muse, mutect2, varscan2
- OR11H1 | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 137/1346 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1285670716; called by muse, varscan2
- OR14A16 | c.298T>C p.F100L | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as COSV104423880; called by muse, mutect2, varscan2
- OR4N2 | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 127/781 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.075); catalogued as COSV60051284; called by muse, mutect2, varscan2
- OR5AR1 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 131/367 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs970563426; called by muse, mutect2, varscan2
- OR6Y1 | c.716G>T p.R239L | Missense Mutation (SNP) | VAF 131/339 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56929021; called by muse, mutect2, varscan2
- PCCA | c.1044G>T p.L348F | Missense Mutation (SNP) | VAF 163/411 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100887078; called by muse, mutect2, varscan2
- PCDH11X | c.3817C>A p.Q1273K | Missense Mutation (SNP) | VAF 142/778 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV53499277; called by muse, mutect2, varscan2
- PCDHAC1 | c.100G>T p.V34L | Missense Mutation (SNP) | VAF 49/79 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as rs782029930; called by muse, mutect2, varscan2
- PDE11A | c.1167G>T p.L389F | Missense Mutation (SNP) | VAF 98/211 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1378399516; called by muse, mutect2, varscan2
- PEX1 | c.179G>T p.W60L | Missense Mutation (SNP) | VAF 266/474 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50400127; called by muse, mutect2, varscan2
- PKHD1L1 | c.6508G>A p.D2170N | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.137); catalogued as rs745316797; called by muse, mutect2, varscan2
- PLEC | c.626A>G p.D209G (on ENST00000322810 / NM_201380.4; = p.D99G on NM_000445.5) | Missense Mutation (SNP) | VAF 168/494 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59691850; called by muse, mutect2, varscan2
- PRSS48 | c.636G>A p.M212I | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs1282971049; called by muse, mutect2, varscan2
- PTCH1 | c.2974del p.E992Kfs*3 | Frame Shift Del (DEL) | VAF 217/448 reads (48%) | catalogued as COSV59464041; called by mutect2, pindel, varscan2
- PTN | c.340G>C p.A114P | Missense Mutation (SNP) | VAF 147/288 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV100781060, COSV61965817; called by muse, mutect2, varscan2
- PTPRD | c.4764G>C p.M1588I | Missense Mutation (SNP) | VAF 70/152 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV61952971, COSV61957972; called by muse, mutect2, varscan2
- PTPRK | c.2890G>A p.E964K (on ENST00000368215 / NM_001291984.2; = p.E965K on NM_002844.4) | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs868817217, COSV100951308; called by muse, mutect2, varscan2
- PWWP3B | c.809C>G p.S270C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.912); catalogued as rs373277353; called by muse, mutect2, varscan2
- QRICH2 | c.2359C>G p.Q787E | Missense Mutation (SNP) | VAF 108/167 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.318); catalogued as COSV53158594; called by muse, mutect2, varscan2
- RAB3IP | c.1105C>G p.L369V (on ENST00000550536 / NM_175623.4; = p.L353V on NM_022456.5) | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs763550047; called by muse, mutect2, varscan2
- RB1 | c.2659G>A p.G887R | Missense Mutation (SNP) | VAF 138/259 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs777789154; called by muse, mutect2, varscan2
- RBBP4 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 240/478 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV65132941; called by muse, mutect2, varscan2
- RBM14 | c.806A>G p.Q269R | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as rs1298039039; called by muse, mutect2, varscan2
- REG1B | c.468G>T p.K156N | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.029); catalogued as COSV59307415; called by muse, mutect2, varscan2
- RIMS2 | c.1632G>C p.M544I (on ENST00000666250 / NM_001348490.2; = p.M352I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.224); catalogued as COSV51658804; called by muse, mutect2, varscan2
- RP1 | c.4689G>T p.M1563I | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99609220; called by muse, mutect2, varscan2
- RP1 | c.4690G>T p.V1564L | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as rs1413225544; called by muse, mutect2, varscan2
- RYR3 | c.5552C>A p.A1851D | Missense Mutation (SNP) | VAF 129/371 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101213508; called by muse, mutect2, varscan2
- RYR3 | c.10480C>G p.P3494A (on ENST00000389232; = p.P3495A on NM_001036.6) | Missense Mutation (SNP) | VAF 112/302 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1373033376; called by muse, mutect2, varscan2
- SCAF8 | c.3241C>G p.R1081G | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.873); catalogued as rs773792042; called by muse, mutect2, varscan2
- SELENOP | c.282C>G p.I94M | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs778089674, COSV100736790; called by muse, mutect2, varscan2
- SERPINB10 | c.975G>T p.M325I | Missense Mutation (SNP) | VAF 63/100 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as COSV53074486; called by muse, mutect2, varscan2
- SETDB2 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV99033756; called by muse, mutect2, varscan2
- SLC12A4 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as rs924146508; called by muse, mutect2, varscan2
- SLC39A5 | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 126/385 reads (33%) | SIFT tolerated (0.3); PolyPhen probably damaging (1); catalogued as rs144543042, COSV57193075; called by muse, mutect2, varscan2
- SLC45A2 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 110/322 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.103); catalogued as rs949276381; called by muse, mutect2, varscan2
- SLITRK3 | c.2203C>A p.P735T | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV99578585; called by muse, mutect2, varscan2
- SNRNP40 | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 66/233 reads (28%) | catalogued as rs1310406154; called by muse, mutect2, varscan2
- SPHKAP | c.3956G>A p.R1319H | Missense Mutation (SNP) | VAF 69/127 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs747530276, COSV60892427; called by muse, mutect2, varscan2
- SRMS | c.835G>T p.G279C | Missense Mutation (SNP) | VAF 67/207 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV99420676; called by muse, mutect2, varscan2
- STARD6 | c.325C>G p.R109G | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200226447, COSV100323329; called by muse, mutect2, varscan2
- STON1 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 94/237 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs552830913; called by muse, mutect2, varscan2
- SYCP1 | c.2312G>C p.R771T | Missense Mutation (SNP) | VAF 71/188 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV101050851; called by muse, mutect2, varscan2
- TANC1 | c.1900C>T p.Q634* | Nonsense Mutation (SNP) | VAF 84/166 reads (51%) | catalogued as COSV55095690, COSV55098839; called by muse, mutect2, varscan2
- TENM3 | c.2968-1G>T p.X990_splice | Splice Site (SNP) | VAF 83/124 reads (67%) | catalogued as COSV69312213; called by muse, mutect2, varscan2
- TERT | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 91/338 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.284); catalogued as rs1060503002, COSV57204643; called by muse, mutect2, varscan2
- TGDS | c.562G>T p.V188F | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs1183728299; called by muse, mutect2, varscan2
- THBS3 | c.1885G>A p.G629R | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs757393682; called by muse, mutect2, varscan2
- TTN | c.66250G>A p.D22084N (on ENST00000591111; = p.D14660N on NM_003319.4) | Missense Mutation (SNP) | VAF 32/52 reads (62%) | PolyPhen probably damaging (0.998); catalogued as COSV60383453; called by muse, mutect2, varscan2
- UTP20 | c.4823C>A p.S1608Y | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as COSV55379166; called by muse, mutect2, varscan2
- ZFHX4 | c.961A>G p.I321V | Missense Mutation (SNP) | VAF 67/248 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1204161129; called by muse, mutect2, varscan2
- ZFHX4 | c.1155C>G p.S385R | Missense Mutation (SNP) | VAF 67/214 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.864); catalogued as rs367633059; called by muse, mutect2, varscan2
- ZNF185 | c.546C>A p.S182R | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59278339; called by muse, mutect2, varscan2
- ZNF235 | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 71/112 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as COSV52158506; called by muse, mutect2, varscan2
- ABCD1 | c.1604C>T p.P535L | Missense Mutation (SNP) | VAF 79/183 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- ACADM | c.205A>G p.K69E | Missense Mutation (SNP) | VAF 106/342 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2
- ADAMTS18 | c.3112G>C p.E1038Q | Missense Mutation (SNP) | VAF 71/109 reads (65%) | SIFT tolerated (0.46); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADAMTS19 | c.2434G>C p.E812Q | Missense Mutation (SNP) | VAF 98/182 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADAMTS20 | c.3461C>T p.A1154V | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ADAR | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 61/191 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- AEBP2 | c.1220G>C p.R407T | Missense Mutation (SNP) | VAF 133/536 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- AFDN | c.2854T>G p.L952V | Missense Mutation (SNP) | VAF 124/195 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- AKR1B15 | c.887C>A p.A296E | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ALX1 | c.161G>C p.G54A | Missense Mutation (SNP) | VAF 121/260 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AMOT | c.1771G>A p.E591K (on ENST00000371959 / NM_001113490.1; = p.E182K on NM_133265.3) | Missense Mutation (SNP) | VAF 82/229 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- ANK3 | c.10267G>A p.E3423K | Missense Mutation (SNP) | VAF 103/168 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ANO4 | c.1631A>G p.N544S (on ENST00000392977 / NM_001286615.2; = p.N509S on NM_178826.4) | Missense Mutation (SNP) | VAF 79/268 reads (29%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- AP1M1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- APBA2 | c.709C>A p.L237M | Missense Mutation (SNP) | VAF 143/549 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- APBA2 | c.914G>T p.R305M | Missense Mutation (SNP) | VAF 146/363 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- ARID3A | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 138/217 reads (64%) | called by muse, varscan2
- BHMT | c.434T>A p.L145* | Nonsense Mutation (SNP) | VAF 62/105 reads (59%) | called by muse, mutect2, varscan2
- C1orf105 | c.305A>G p.D102G | Missense Mutation (SNP) | VAF 90/223 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA1E | c.6487C>T p.P2163S (on ENST00000367573 / NM_001205293.3; = p.P2120S on NM_000721.4) | Missense Mutation (SNP) | VAF 85/134 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CAMSAP1 | c.3562G>T p.A1188S | Missense Mutation (SNP) | VAF 98/148 reads (66%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CATSPERE | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 95/187 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CCM2L | c.76C>A p.R26S | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CCNA1 | c.916C>G p.P306A | Missense Mutation (SNP) | VAF 108/179 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CD109 | c.464C>G p.S155* | Nonsense Mutation (SNP) | VAF 86/208 reads (41%) | called by muse, mutect2, varscan2
- CFAP54 | c.4988del p.T1663Nfs*28 | Frame Shift Del (DEL) | VAF 76/270 reads (28%) | called by mutect2, varscan2
- CLEC4C | c.146G>T p.S49I | Missense Mutation (SNP) | VAF 69/202 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- CMKLR1 | c.803C>T p.T268I (on ENST00000312143 / NM_001142344.2; = p.T266I on NM_004072.3) | Missense Mutation (SNP) | VAF 96/324 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- COL21A1 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 154/493 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL4A5 | c.4648C>G p.Q1550E | Missense Mutation (SNP) | VAF 14/523 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.055); called by muse, mutect2
- CR2 | c.2926G>T p.V976F | Missense Mutation (SNP) | VAF 85/200 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRACD | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSRNP2 | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- CST5 | c.194A>G p.Y65C | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2
- CUX1 | c.2521G>T p.A841S | Missense Mutation (SNP) | VAF 95/353 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CYP3A5 | c.1247C>G p.P416R | Missense Mutation (SNP) | VAF 104/177 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CYP4F3 | c.1438G>T p.V480L | Missense Mutation (SNP) | VAF 114/168 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- CYTH1 | c.435A>T p.L145= | Splice Region (SNP) | VAF 124/188 reads (66%) | called by muse, mutect2, varscan2
- DCLK1 | c.1998G>C p.K666N | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- DGKG | c.1117-2del p.X373_splice | Splice Site (DEL) | VAF 204/501 reads (41%) | called by mutect2, varscan2*
- DIPK1B | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 106/174 reads (61%) | called by muse, mutect2, varscan2
- DIPK2B | c.905A>T p.N302I | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- DISP2 | c.2741G>A p.S914N | Missense Mutation (SNP) | VAF 64/153 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DMXL2 | c.285+6T>A | Splice Region (SNP) | VAF 30/95 reads (32%) | called by muse, mutect2, varscan2
- DNAH12 | c.7739C>T p.S2580L (on ENST00000351747; = p.S3448L on NM_001366028.2) | Missense Mutation (SNP) | VAF 83/140 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- DOC2A | c.860C>G p.S287W | Missense Mutation (SNP) | VAF 50/80 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK1 | c.2371G>T p.V791F | Missense Mutation (SNP) | VAF 132/222 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DRAM2 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 75/503 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSG4 | c.534G>T p.K178N | Missense Mutation (SNP) | VAF 88/328 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DST | c.9484G>T p.V3162F | Missense Mutation (SNP) | VAF 70/111 reads (63%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- DTNB | c.1632G>A p.M544I | Missense Mutation (SNP) | VAF 76/243 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- EFCAB8 | c.568-10_571del p.X190_splice | Splice Site (DEL) | VAF 48/115 reads (42%) | called by mutect2, pindel*, varscan2
- EIF2D | c.1142T>G p.I381R | Missense Mutation (SNP) | VAF 67/108 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ERICH3 | c.2047G>T p.G683C | Missense Mutation (SNP) | VAF 137/393 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- ESPL1 | c.925C>G p.Q309E | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESYT1 | c.1570G>C p.V524L | Missense Mutation (SNP) | VAF 159/482 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- ESYT1 | c.2113G>C p.E705Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FADS2 | c.744G>T p.E248D | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAM135B | c.3791-2A>T p.X1264_splice | Splice Site (SNP) | VAF 68/185 reads (37%) | called by muse, mutect2, varscan2
- FCRL5 | c.1918C>A p.L640I | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- FCRL5 | c.134A>G p.K45R | Missense Mutation (SNP) | VAF 121/411 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- FERMT3 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 103/272 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- FSCB | c.682G>T p.V228L | Missense Mutation (SNP) | VAF 107/330 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- FUNDC2 | c.70del p.R24Afs*116 | Frame Shift Del (DEL) | VAF 99/341 reads (29%) | called by mutect2, pindel, varscan2
- GAB3 | c.1647A>G p.K549= | Splice Region (SNP) | VAF 87/205 reads (42%) | called by muse, mutect2, varscan2
- GABRA5 | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 78/332 reads (23%) | called by muse, mutect2, varscan2
- GAPVD1 | c.3178C>T p.H1060Y | Missense Mutation (SNP) | VAF 68/118 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAREM1 | c.1769G>C p.S590T (on ENST00000269209 / NM_001242409.2; = p.S589T on NM_022751.3) | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.057); called by muse, varscan2
- GCDH | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 49/67 reads (73%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- GDAP2 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 238/436 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- GLDN | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 163/466 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- GLMN | c.683A>T p.Q228L | Missense Mutation (SNP) | VAF 116/375 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- GLRX3 | c.114C>G p.F38L | Missense Mutation (SNP) | VAF 65/98 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GNAS | c.1156A>T p.M386L | Missense Mutation (SNP) | VAF 130/352 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- GOLGA5 | c.541C>T p.H181Y | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GOLGA6L2 | c.2673del p.R892Efs*86 | Frame Shift Del (DEL) | VAF 54/194 reads (28%) | called by pindel, varscan2
- GPC6 | c.1048del p.L350Sfs*39 | Frame Shift Del (DEL) | VAF 229/741 reads (31%) | called by mutect2, pindel, varscan2
- GUCY2F | c.3064A>T p.I1022F | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HAO1 | c.1046G>C p.C349S | Missense Mutation (SNP) | VAF 77/272 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- HDAC9 | c.3049G>T p.V1017L (on ENST00000441542 / NM_178425.3; = p.V1014L on NM_178423.3) | Missense Mutation (SNP) | VAF 106/306 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HDC | c.1109G>T p.G370V | Missense Mutation (SNP) | VAF 189/520 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HELZ | c.4430C>G p.S1477* | Nonsense Mutation (SNP) | VAF 68/107 reads (64%) | called by muse, mutect2, varscan2
- HNRNPD | c.496G>T p.V166L | Missense Mutation (SNP) | VAF 92/252 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- HNRNPD | c.495G>T p.K165N | Missense Mutation (SNP) | VAF 88/247 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- HNRNPH2 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 65/140 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HRG | c.732C>A p.F244L | Missense Mutation (SNP) | VAF 376/877 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- HS6ST3 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HUS1 | c.62A>G p.N21S | Missense Mutation (SNP) | VAF 63/114 reads (55%) | SIFT tolerated (0.81); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IFNA14 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 156/299 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- IGHV2-26 | c.331A>T p.T111S | Missense Mutation (SNP) | VAF 242/498 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGHV4-59 | c.329C>A p.A110D | Missense Mutation (SNP) | VAF 97/596 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- IGKV1D-42 | c.107C>G p.S36C | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IL12RB1 | c.1174G>T p.D392Y | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IL18RAP | c.178A>T p.N60Y | Missense Mutation (SNP) | VAF 124/464 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- IL27RA | c.1906G>C p.A636P | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- IPO7 | c.1879G>C p.E627Q | Missense Mutation (SNP) | VAF 46/73 reads (63%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IRF5 | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 94/134 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- IRS4 | c.2418C>G p.S806R | Missense Mutation (SNP) | VAF 106/398 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- ISLR2 | c.1765T>C p.S589P | Missense Mutation (SNP) | VAF 99/271 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ITGAV | c.2173G>C p.A725P | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ITPR3 | c.1929C>G p.I643M | Missense Mutation (SNP) | VAF 88/157 reads (56%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- KCTD5 | c.29C>A p.S10* | Nonsense Mutation (SNP) | VAF 9/13 reads (69%) | called by muse, mutect2, varscan2
- KIAA1210 | c.3190C>G p.L1064V | Missense Mutation (SNP) | VAF 98/278 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- KIAA1755 | c.3250G>C p.V1084L | Missense Mutation (SNP) | VAF 68/180 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KIF26A | c.5626G>C p.G1876R | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- KLHL23 | c.1418G>A p.G473E | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KMT2D | c.16106C>A p.T5369K | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- KRT6C | c.930G>C p.Q310H | Missense Mutation (SNP) | VAF 277/830 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- KRT77 | c.1151A>G p.E384G | Missense Mutation (SNP) | VAF 118/284 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KRT8 | c.1288C>G p.L430V | Missense Mutation (SNP) | VAF 118/273 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- L1CAM | c.2347C>A p.P783T | Missense Mutation (SNP) | VAF 74/237 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LATS1 | c.2106G>C p.K702N | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- LIFR | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 192/526 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRCH2 | c.923G>T p.R308I | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LRRC73 | c.214A>T p.S72C | Missense Mutation (SNP) | VAF 63/93 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- LRRTM1 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 85/214 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- MCCC1 | c.469A>G p.I157V | Missense Mutation (SNP) | VAF 127/379 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MDGA2 | c.387G>T p.L129F | Missense Mutation (SNP) | VAF 159/369 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MINAR2 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 163/337 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MME | c.2162G>T p.G721V | Missense Mutation (SNP) | VAF 539/705 reads (76%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MMP27 | c.687T>A p.D229E | Missense Mutation (SNP) | VAF 88/287 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); called by muse, varscan2
- MRPS24 | c.499C>G p.L167V | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, varscan2
- MTMR6 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 132/283 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- MUC16 | c.3520C>A p.Q1174K | Missense Mutation (SNP) | VAF 99/174 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- MYH10 | c.425A>T p.Y142F | Missense Mutation (SNP) | VAF 84/125 reads (67%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MYO16 | c.2200G>T p.E734* | Nonsense Mutation (SNP) | VAF 83/248 reads (33%) | called by muse, mutect2, varscan2
- NAXD | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NBAS | c.989G>T p.G330V | Missense Mutation (SNP) | VAF 194/503 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NCKAP1 | c.295G>C p.D99H | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2
- NOC4L | c.1431+1G>C p.X477_splice | Splice Site (SNP) | VAF 50/144 reads (35%) | called by muse, mutect2, varscan2
- NOTCH1 | c.924del p.N308Kfs*323 | Frame Shift Del (DEL) | VAF 153/292 reads (52%) | called by mutect2, pindel, varscan2
- NOTCH2 | c.6292C>T p.P2098S | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NPC1 | c.1191G>T p.Q397H | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- NR2E1 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 192/602 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- NRP1 | c.1463A>T p.D488V | Missense Mutation (SNP) | VAF 101/152 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRSN1 | c.311A>T p.H104L | Missense Mutation (SNP) | VAF 208/401 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- NRXN3 | c.2183G>C p.R728T (on ENST00000335750 / NM_001330195.2; = p.R355T on NM_004796.6) | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- NTRK1 | c.56C>A p.P19Q | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NXPE3 | c.647C>G p.S216* | Nonsense Mutation (SNP) | VAF 67/178 reads (38%) | called by muse, mutect2, varscan2
- OPHN1 | c.1349A>T p.K450I | Missense Mutation (SNP) | VAF 93/307 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- OR11H1 | c.161G>T p.W54L | Missense Mutation (SNP) | VAF 138/1308 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, varscan2
- OR2M3 | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 94/192 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR4F4 | c.545G>A p.C182Y | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- OR4K1 | c.299A>T p.Q100L | Missense Mutation (SNP) | VAF 91/610 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- OR4K5 | c.432G>T p.L144F | Missense Mutation (SNP) | VAF 101/826 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- OR56A3 | c.176T>G p.L59R | Missense Mutation (SNP) | VAF 98/160 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- OR56B4 | c.695T>A p.L232Q | Missense Mutation (SNP) | VAF 124/197 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- OR7G1 | c.217T>G p.L73V | Missense Mutation (SNP) | VAF 63/110 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.066); called by muse, varscan2
- OR8A1 | c.448G>T p.A150S | Missense Mutation (SNP) | VAF 77/204 reads (38%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- OXR1 | c.278A>T p.Q93L (on ENST00000442977 / NM_001198532.1; = p.Q92L on NM_018002.3) | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- PAK6 | c.1057dup p.R353Pfs*28 | Frame Shift Ins (INS) | VAF 32/118 reads (27%) | called by pindel, varscan2
- PAK6 | c.1185G>T p.R395S | Missense Mutation (SNP) | VAF 102/284 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.321); called by muse, varscan2
- PASD1 | c.2093A>C p.D698A | Missense Mutation (SNP) | VAF 155/457 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PCDH15 | c.5067G>T p.R1689S (on ENST00000644397 / NM_001354429.2; = p.R1631S on NM_001142771.2) | Missense Mutation (SNP) | VAF 246/474 reads (52%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH7 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- PCDH8 | c.535A>G p.S179G | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PDE6C | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 189/318 reads (59%) | SIFT tolerated (0.28); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- PHF6 | c.880A>G p.I294V | Missense Mutation (SNP) | VAF 77/138 reads (56%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PIN1 | c.145C>A p.Q49K | Missense Mutation (SNP) | VAF 170/267 reads (64%) | SIFT tolerated (0.92); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PIN4 | c.148G>A p.D50N (on ENST00000664196; = p.D25N on NM_006223.4) | Missense Mutation (SNP) | VAF 154/469 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- PKHD1 | c.7712T>C p.F2571S | Missense Mutation (SNP) | VAF 92/204 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PKHD1L1 | c.5275G>C p.V1759L | Missense Mutation (SNP) | VAF 119/366 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLEKHH1 | c.3085G>C p.E1029Q | Missense Mutation (SNP) | VAF 85/408 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PLPP7 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 114/168 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNB3 | c.2917G>A p.V973M | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- PMPCB | c.303C>G p.H101Q | Missense Mutation (SNP) | VAF 123/292 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- POLR1A | c.4991C>T p.S1664L | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POLR2A | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- POLR2B | c.740C>G p.A247G | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPAT | c.489_496del p.Q163Hfs*9 | Frame Shift Del (DEL) | VAF 30/114 reads (26%) | called by mutect2, pindel, varscan2
- PSG9 | c.546G>A p.M182I | Missense Mutation (SNP) | VAF 14/398 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.091); called by muse, mutect2
- PSMC1 | c.1213A>C p.M405L | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTGER2 | c.721G>T p.G241C | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTN | c.140G>T p.C47F | Missense Mutation (SNP) | VAF 65/103 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- PTPRC | c.1570del p.A524Lfs*18 | Frame Shift Del (DEL) | VAF 145/335 reads (43%) | called by mutect2, pindel, varscan2
- PTPRC | c.3441del p.K1147Nfs*37 | Frame Shift Del (DEL) | VAF 91/254 reads (36%) | called by pindel, varscan2
- PUM2 | c.2953G>T p.G985C | Missense Mutation (SNP) | VAF 102/393 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- RAB3IP | c.1039C>T p.P347S (on ENST00000550536 / NM_175623.4; = p.P331S on NM_022456.5) | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RAB3IP | c.1040C>T p.P347L (on ENST00000550536 / NM_175623.4; = p.P331L on NM_022456.5) | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RALGDS | c.1174G>C p.E392Q | Missense Mutation (SNP) | VAF 166/257 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RASA3 | c.1737A>T p.K579N | Missense Mutation (SNP) | VAF 79/226 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RBM23 | c.514C>G p.Q172E (on ENST00000359890 / NM_001077351.2; = p.Q156E on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/321 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- RCN1 | c.941G>C p.G314A | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- RELN | c.4694del p.P1565Hfs*32 | Frame Shift Del (DEL) | VAF 81/410 reads (20%) | called by mutect2, pindel, varscan2
- RELN | c.3764G>A p.W1255* | Nonsense Mutation (SNP) | VAF 188/873 reads (22%) | called by muse, mutect2, varscan2
- REV3L | c.9253-1G>C p.X3085_splice | Splice Site (SNP) | VAF 35/93 reads (38%) | called by muse, mutect2, varscan2
- RFC1 | c.3301G>T p.E1101* (on ENST00000381897 / NM_001363496.2; = p.E1100* on NM_002913.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 95/172 reads (55%) | called by muse, mutect2, varscan2
- RGS4 | c.278T>A p.I93N | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- RGS5 | c.44T>A p.M15K | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROS1 | c.3381G>T p.Q1127H | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- RPE65 | c.812G>A p.W271* | Nonsense Mutation (SNP) | VAF 159/509 reads (31%) | called by muse, mutect2, varscan2
- RPS6KL1 | c.1539+7T>A | Splice Region (SNP) | VAF 95/209 reads (45%) | called by muse, mutect2, varscan2
- RYR2 | c.5627A>C p.Q1876P | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0); called by mutect2, varscan2
- SAMD9 | c.1344C>G p.I448M | Missense Mutation (SNP) | VAF 96/175 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCGB2A1 | c.163G>T p.A55S | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SDC1 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SF3B2 | c.105G>C p.K35N | Missense Mutation (SNP) | VAF 75/221 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SFT2D3 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 68/86 reads (79%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SH3D19 | c.1371G>T p.K457N | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- SH3KBP1 | c.1325C>A p.A442D | Missense Mutation (SNP) | VAF 75/303 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SH3RF3 | c.2337G>C p.E779D | Missense Mutation (SNP) | VAF 76/247 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- SLC10A3 | c.1001T>C p.I334T | Missense Mutation (SNP) | VAF 103/310 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC25A32 | c.925G>C p.D309H | Missense Mutation (SNP) | VAF 148/454 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SLC29A1 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 197/283 reads (70%) | called by muse, mutect2, varscan2
- SLC41A3 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 66/76 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- SLC4A11 | c.1897+3G>C | Splice Region (SNP) | VAF 121/272 reads (44%) | called by muse, mutect2, varscan2
- SLC6A15 | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SMARCC1 | c.1511A>T p.E504V | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- SMARCC1 | c.1510G>T p.E504* | Nonsense Mutation (SNP) | VAF 56/108 reads (52%) | called by muse, mutect2, varscan2
- SMG1 | c.9151G>T p.D3051Y | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- SOX17 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 116/148 reads (78%) | SIFT tolerated (0.25); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SOX5 | c.964A>T p.T322S | Missense Mutation (SNP) | VAF 398/682 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- SPAG9 | c.2362dup p.C788Lfs*73 (on ENST00000262013 / NM_001130528.3; = p.C774Lfs*73 on NM_003971.6) | Frame Shift Ins (INS) | VAF 141/238 reads (59%) | called by mutect2, pindel, varscan2
- SRRM2 | c.1994G>T p.R665I | Missense Mutation (SNP) | VAF 137/206 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- STAB2 | c.3879C>A p.C1293* | Nonsense Mutation (SNP) | VAF 88/334 reads (26%) | called by muse, mutect2, varscan2
- STARD8 | c.2611G>T p.A871S | Missense Mutation (SNP) | VAF 83/238 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STT3A | c.1114C>G p.P372A | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUPT20H | c.913G>A p.E305K (on ENST00000350612 / NM_001014286.3; = p.E306K on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- TAS2R8 | c.379G>C p.D127H | Missense Mutation (SNP) | VAF 205/346 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- TC2N | c.743G>C p.R248T | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, varscan2
- TENM2 | c.4210G>A p.D1404N (on ENST00000518659 / NM_001122679.2; = p.D1165N on NM_001080428.3) | Missense Mutation (SNP) | VAF 302/443 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TFAM | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 130/258 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TGFBR3 | c.196G>T p.V66F | Missense Mutation (SNP) | VAF 313/575 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- THSD4 | c.2933A>G p.K978R | Missense Mutation (SNP) | VAF 120/261 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TMEM132C | c.3098G>T p.G1033V | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TMEM167A | c.188T>C p.V63A | Missense Mutation (SNP) | VAF 68/243 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM19 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 131/327 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- TNFAIP8L1 | c.406A>T p.T136S | Missense Mutation (SNP) | VAF 62/105 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TNS2 | c.436C>G p.P146A (on ENST00000314250 / NM_170754.4; = p.P156A on NM_015319.2) | Missense Mutation (SNP) | VAF 75/194 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TONSL | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TRBV4-2 | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM43B | c.176C>A p.S59* | Nonsense Mutation (SNP) | VAF 130/532 reads (24%) | called by muse, mutect2, varscan2
- TTC13 | c.2094-1G>C p.X698_splice | Splice Site (SNP) | VAF 45/88 reads (51%) | called by muse, mutect2, varscan2
- TTC14 | c.289C>G p.H97D | Missense Mutation (SNP) | VAF 49/284 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TTC28 | c.6692T>A p.V2231D | Missense Mutation (SNP) | VAF 138/238 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TTLL13P | c.2393C>G p.S798C | Missense Mutation (SNP) | VAF 107/258 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- TTYH1 | c.449C>G p.A150G | Missense Mutation (SNP) | VAF 169/206 reads (82%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TXNDC11 | c.1993C>G p.Q665E (on ENST00000356957 / NM_001303447.2; = p.Q638E on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/107 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- UBE3D | c.693G>C p.E231D | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- UBN2 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- UBR5 | c.1710C>G p.D570E | Missense Mutation (SNP) | VAF 134/370 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- UGT2B11 | c.496A>T p.I166L | Missense Mutation (SNP) | VAF 139/373 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- UMODL1 | c.1838G>C p.R613T | Missense Mutation (SNP) | VAF 11/316 reads (3%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.796); called by muse, mutect2
- USP43 | c.1014C>G p.F338L | Missense Mutation (SNP) | VAF 95/153 reads (62%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- USP47 | c.2560G>A p.D854N (on ENST00000399455 / NM_001372095.1; = p.D766N on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- VPS45 | c.1332T>A p.D444E | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.596); called by muse, mutect2
- WDR17 | c.1211A>T p.D404V | Missense Mutation (SNP) | VAF 108/159 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- WDR44 | c.2313G>C p.L771F | Missense Mutation (SNP) | VAF 83/235 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WDR47 | c.2002G>T p.A668S (on ENST00000369962 / NM_001142551.2; = p.A669S on NM_014969.5) | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR72 | c.2953-1G>A p.X985_splice | Splice Site (SNP) | VAF 48/180 reads (27%) | called by muse, mutect2, varscan2
- XPOT | c.1875G>A p.M625I | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZIC4 | c.224C>A p.P75Q | Missense Mutation (SNP) | VAF 66/75 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- ZKSCAN8 | c.610G>C p.D204H | Missense Mutation (SNP) | VAF 72/142 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- ZMYND15 | c.1452del p.L485* | Frame Shift Del (DEL) | VAF 104/229 reads (45%) | called by mutect2, pindel, varscan2
- ZNF484 | c.1153G>C p.E385Q | Missense Mutation (SNP) | VAF 76/130 reads (58%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- ZNF599 | c.990G>C p.M330I | Missense Mutation (SNP) | VAF 85/380 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ZNF750 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 113/206 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ZSWIM8 | c.394G>T p.D132Y | Missense Mutation (SNP) | VAF 174/297 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ABCB4 | c.2226C>G p.G742= | Silent (SNP) | VAF 120/262 reads (46%) | catalogued as COSV55934985; called by muse, mutect2, varscan2
- ABCC2 | c.3015T>C p.S1005= | Silent (SNP) | VAF 201/360 reads (56%) | called by muse, mutect2, varscan2
- AC006059.2 | c.2187C>A p.A729= | Silent (SNP) | VAF 41/60 reads (68%) | catalogued as COSV59610097; called by muse, mutect2, varscan2
- ADAMTS5 | c.2082T>C p.S694= | Silent (SNP) | VAF 66/247 reads (27%) | called by muse, mutect2, varscan2
- ADGRB2 | c.978G>T p.G326= | Silent (SNP) | VAF 213/383 reads (56%) | called by muse, mutect2, varscan2
- AKAP9 | c.3201A>G p.Q1067= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as rs1554405607, COSV62337859; ClinVar: likely benign; called by muse, mutect2, varscan2
- ALDH1A3 | c.633C>G p.L211= | Silent (SNP) | VAF 92/413 reads (22%) | called by muse, mutect2, varscan2
- ATG2A | c.3831C>T p.L1277= | Silent (SNP) | VAF 76/189 reads (40%) | called by muse, mutect2, varscan2
- ATP1A2 | c.537C>T p.N179= | Silent (SNP) | VAF 156/389 reads (40%) | catalogued as rs759406149; called by muse, mutect2, varscan2
- ATP2C1 | c.2514C>T p.L838= | Silent (SNP) | VAF 63/290 reads (22%) | called by muse, varscan2
- BAHD1 | c.1371G>T p.L457= | Silent (SNP) | VAF 23/95 reads (24%) | called by muse, mutect2, varscan2
- C2CD2L | c.633T>C p.D211= | Silent (SNP) | VAF 67/220 reads (30%) | called by muse, mutect2, varscan2
- CCDC191 | c.1254G>T p.L418= | Silent (SNP) | VAF 116/386 reads (30%) | catalogued as COSV55676202; called by muse, mutect2, varscan2
- CCDC38 | c.1416C>A p.L472= | Silent (SNP) | VAF 146/380 reads (38%) | called by muse, mutect2, varscan2
- CCNL1 | c.564G>T p.V188= | Silent (SNP) | VAF 70/150 reads (47%) | called by muse, varscan2
- CDH10 | c.2295C>A p.L765= | Silent (SNP) | VAF 71/181 reads (39%) | catalogued as COSV52586467; called by muse, mutect2, varscan2
- CDX1 | c.708C>T p.A236= | Silent (SNP) | VAF 28/44 reads (64%) | catalogued as rs752522350, COSV51568871; called by muse, mutect2, varscan2
- CEP295 | c.3285G>A p.G1095= | Silent (SNP) | VAF 63/214 reads (29%) | catalogued as rs878910312; called by muse, mutect2, varscan2
- CFAP20DC | c.1662A>G p.L554= | Silent (SNP) | VAF 93/159 reads (58%) | catalogued as rs1290440679; called by muse, mutect2, varscan2
- CFAP54 | c.4989A>T p.T1663= | Silent (SNP) | VAF 78/270 reads (29%) | called by mutect2, varscan2
- CLRN2 | c.588T>C p.A196= | Silent (SNP) | VAF 194/325 reads (60%) | called by muse, mutect2, varscan2
- CLUH | c.2229G>T p.L743= (on ENST00000435359; = p.L782= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 86/292 reads (29%) | called by muse, mutect2, varscan2
- COG2 | c.1710G>A p.K570= | Silent (SNP) | VAF 156/279 reads (56%) | catalogued as rs955064520; called by muse, mutect2, varscan2
- COL18A1 | c.1773C>G p.L591= (on ENST00000359759 / NM_130444.3; = p.L356= on NM_030582.4) | Silent (SNP) | VAF 91/262 reads (35%) | called by muse, mutect2, varscan2
- COL25A1 | c.378G>T p.G126= | Silent (SNP) | VAF 61/146 reads (42%) | catalogued as COSV101211292; called by muse, mutect2, varscan2
- COLEC12 | c.942G>T p.L314= | Silent (SNP) | VAF 108/372 reads (29%) | called by muse, mutect2, varscan2
- CRELD1 | c.63C>G p.L21= | Silent (SNP) | VAF 161/228 reads (71%) | catalogued as COSV55974234; called by muse, mutect2, varscan2
- CTTNBP2NL | c.192G>A p.L64= | Silent (SNP) | VAF 114/280 reads (41%) | called by muse, mutect2, varscan2
- CUBN | c.6363C>T p.H2121= | Silent (SNP) | VAF 140/231 reads (61%) | catalogued as rs752850780; called by muse, mutect2, varscan2
- CUX2 | c.534G>T p.L178= | Silent (SNP) | VAF 93/265 reads (35%) | called by muse, mutect2, varscan2
- CYP3A4 | c.285G>A p.V95= | Silent (SNP) | VAF 86/512 reads (17%) | called by muse, mutect2, varscan2
- DCHS1 | c.8236T>C p.L2746= | Silent (SNP) | VAF 207/338 reads (61%) | called by muse, mutect2, varscan2
- DCLK2 | c.309C>G p.L103= | Silent (SNP) | VAF 98/261 reads (38%) | called by muse, mutect2, varscan2
- DGAT1 | c.885G>C p.L295= | Silent (SNP) | VAF 29/109 reads (27%) | called by muse, mutect2, varscan2
- DOHH | c.663G>A p.A221= | Silent (SNP) | VAF 68/103 reads (66%) | catalogued as rs1371839598; called by muse, mutect2, varscan2
- DSP | c.4992G>A p.L1664= | Silent (SNP) | VAF 218/807 reads (27%) | called by muse, mutect2, varscan2
- EEF1A2 | c.921C>T p.N307= | Silent (SNP) | VAF 134/356 reads (38%) | catalogued as rs1057522085; ClinVar: likely benign; called by muse, varscan2
- EPB42 | c.387C>G p.L129= (on ENST00000441366 / NM_001114134.2; = p.L159= on NM_000119.3) | Silent (SNP) | VAF 195/581 reads (34%) | called by muse, mutect2, varscan2
- ESYT1 | c.426C>G p.L142= | Silent (SNP) | VAF 123/423 reads (29%) | called by muse, mutect2, varscan2
- EYS | c.2895T>G p.L965= | Silent (SNP) | VAF 103/361 reads (29%) | called by muse, mutect2, varscan2
- F8A1 | c.1074C>T p.L358= | Silent (SNP) | VAF 55/164 reads (34%) | catalogued as rs1557274755, COSV100371405; called by mutect2, varscan2
- FAM155B | c.391C>A p.R131= | Silent (SNP) | VAF 87/226 reads (38%) | catalogued as COSV52935460; called by muse, mutect2, varscan2
- FCGBP | c.975T>C p.N325= | Silent (SNP) | VAF 29/46 reads (63%) | called by muse, mutect2, varscan2
- FLNA | c.5553C>A p.I1851= (on ENST00000369850 / NM_001110556.2; = p.I1843= on NM_001456.3) | Silent (SNP) | VAF 78/278 reads (28%) | called by muse, mutect2, varscan2
- FN1 | c.5775G>A p.P1925= | Silent (SNP) | VAF 240/366 reads (66%) | catalogued as rs752013950; called by muse, mutect2, varscan2
- FOXS1 | c.732C>A p.I244= | Silent (SNP) | VAF 118/340 reads (35%) | called by muse, mutect2, varscan2
- GHR | c.1767G>A p.E589= | Silent (SNP) | VAF 118/348 reads (34%) | catalogued as COSV100049631; called by muse, mutect2, varscan2
- GLOD5 | c.84G>A p.Q28= | Silent (SNP) | VAF 34/90 reads (38%) | called by muse, mutect2, varscan2
- GPKOW | c.138G>A p.K46= | Silent (SNP) | VAF 76/221 reads (34%) | called by muse, mutect2, varscan2
- GPR68 | c.405G>A p.L135= | Silent (SNP) | VAF 64/162 reads (40%) | called by muse, mutect2, varscan2
- GREB1 | c.4968C>G p.V1656= | Silent (SNP) | VAF 79/234 reads (34%) | called by muse, mutect2, varscan2
- GRIN1 | c.2148G>A p.E716= | Silent (SNP) | VAF 54/87 reads (62%) | called by muse, mutect2, varscan2
- GRIN3A | c.453G>T p.V151= | Silent (SNP) | VAF 277/486 reads (57%) | called by muse, mutect2, varscan2
- GRM5 | c.1185C>T p.S395= | Silent (SNP) | VAF 141/342 reads (41%) | called by muse, mutect2, varscan2
- GUCY1A1 | c.870C>T p.F290= | Silent (SNP) | VAF 42/130 reads (32%) | called by muse, mutect2, varscan2
- HEATR5A | c.2325T>C p.P775= | Silent (SNP) | VAF 91/265 reads (34%) | called by muse, mutect2, varscan2
- HMGCLL1 | c.165C>A p.V55= | Silent (SNP) | VAF 258/403 reads (64%) | catalogued as COSV99232136; called by muse, mutect2, varscan2
- HS6ST2 | c.192C>T p.T64= | Silent (SNP) | VAF 60/104 reads (58%) | catalogued as rs765888378; called by muse, mutect2, varscan2
- HS6ST3 | c.234C>A p.P78= | Silent (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
- IQUB | c.72T>C p.F24= | Silent (SNP) | VAF 39/70 reads (56%) | called by muse, mutect2, varscan2
- ITPRID1 | c.1680C>T p.S560= | Silent (SNP) | VAF 119/329 reads (36%) | called by muse, mutect2, varscan2
- KCNK10 | c.531T>A p.T177= | Silent (SNP) | VAF 36/99 reads (36%) | called by muse, mutect2, varscan2
- KDM1A | c.1305G>A p.V435= | Silent (SNP) | VAF 27/81 reads (33%) | called by muse, mutect2, varscan2
- KLRF2 | c.558C>T p.S186= | Silent (SNP) | VAF 79/596 reads (13%) | catalogued as rs1300472382; called by muse, mutect2, varscan2
- LCK | c.1155A>T p.L385= | Silent (SNP) | VAF 139/491 reads (28%) | called by muse, mutect2, varscan2
- LDHA | c.111C>T p.I37= | Silent (SNP) | VAF 62/123 reads (50%) | called by muse, mutect2, varscan2
- LUZP4 | c.276A>T p.P92= | Silent (SNP) | VAF 49/182 reads (27%) | called by muse, mutect2, varscan2
- MAMLD1 | c.861C>A p.A287= | Silent (SNP) | VAF 109/252 reads (43%) | called by muse, mutect2, varscan2
- MAP3K5 | c.3678C>G p.L1226= | Silent (SNP) | VAF 150/474 reads (32%) | called by muse, mutect2, varscan2
- MCM3AP | c.150G>T p.S50= | Silent (SNP) | VAF 150/445 reads (34%) | called by muse, mutect2, varscan2
- MCTP1 | c.1086G>A p.L362= | Silent (SNP) | VAF 43/83 reads (52%) | called by muse, mutect2, varscan2
- MPEG1 | c.783C>A p.V261= | Silent (SNP) | VAF 85/261 reads (33%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.144G>T p.V48= | Silent (SNP) | VAF 49/334 reads (15%) | catalogued as rs1218604861; called by muse, mutect2, varscan2
- MYO5B | c.1740G>A p.L580= | Silent (SNP) | VAF 191/333 reads (57%) | called by muse, mutect2, varscan2
- NECAP2 | c.531C>T p.V177= | Silent (SNP) | VAF 114/189 reads (60%) | called by muse, mutect2, varscan2
- NGEF | c.87G>A p.K29= | Silent (SNP) | VAF 189/302 reads (63%) | catalogued as rs1381444738; called by muse, mutect2, varscan2
- NLRP13 | c.2682C>T p.N894= | Silent (SNP) | VAF 191/260 reads (73%) | catalogued as rs1471968331; called by muse, mutect2, varscan2
- NTRK3 | c.346C>A p.R116= | Silent (SNP) | VAF 165/462 reads (36%) | called by muse, mutect2, varscan2
- OLFM1 | c.147C>A p.T49= | Silent (SNP) | VAF 19/32 reads (59%) | called by muse, mutect2, varscan2
- OR52A5 | c.945A>T p.V315= | Silent (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- OR56A3 | c.645C>T p.L215= | Silent (SNP) | VAF 132/204 reads (65%) | called by muse, mutect2, varscan2
- PALM3 | c.279C>G p.S93= (on ENST00000340790; = p.S108= on NM_001145028.2) | Silent (SNP) | VAF 54/78 reads (69%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.1497G>T p.A499= | Silent (SNP) | VAF 97/152 reads (64%) | catalogued as COSV99536694; called by muse, mutect2, varscan2
- PDE2A | c.1012C>A p.R338= | Silent (SNP) | VAF 76/232 reads (33%) | catalogued as rs746253555; called by muse, mutect2, varscan2
- PDIA6 | c.40C>A p.R14= | Silent (SNP) | VAF 148/397 reads (37%) | catalogued as rs61360105; called by muse, mutect2, varscan2
- PIK3R5 | c.1359G>A p.L453= | Silent (SNP) | VAF 156/207 reads (75%) | called by muse, mutect2, varscan2
- PKD1L1 | c.4782C>T p.N1594= | Silent (SNP) | VAF 107/184 reads (58%) | catalogued as rs774860223; called by muse, mutect2, varscan2
- PLCH1 | c.366C>G p.G122= (on ENST00000340059 / NM_001130960.2; = p.G134= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 142/285 reads (50%) | catalogued as COSV100395615; called by muse, mutect2, varscan2
- PLEKHD1 | c.1419G>T p.V473= | Silent (SNP) | VAF 104/293 reads (35%) | called by muse, mutect2, varscan2
- POLA1 | c.4257G>A p.K1419= | Silent (SNP) | VAF 70/195 reads (36%) | called by muse, varscan2
- POLA2 | c.579G>C p.L193= | Silent (SNP) | VAF 88/344 reads (26%) | called by muse, mutect2, varscan2
- POTEE | c.2265C>A p.G755= | Silent (SNP) | VAF 126/361 reads (35%) | catalogued as rs766424794; called by muse, mutect2, varscan2
- RTL3 | c.183C>A p.P61= | Silent (SNP) | VAF 46/139 reads (33%) | catalogued as COSV100329863, COSV58186235; called by muse, mutect2, varscan2
- RUNDC1 | c.387C>T p.F129= | Silent (SNP) | VAF 129/198 reads (65%) | catalogued as rs939251203; called by muse, mutect2, varscan2
- RYR3 | c.5553C>A p.A1851= | Silent (SNP) | VAF 128/368 reads (35%) | called by muse, mutect2, varscan2
- SAV1 | c.978C>A p.L326= | Silent (SNP) | VAF 118/365 reads (32%) | called by muse, mutect2, varscan2
- SH3KBP1 | c.1326C>T p.A442= | Silent (SNP) | VAF 76/308 reads (25%) | catalogued as rs756734324; called by muse, mutect2, varscan2
- SLC49A3 | c.228C>T p.L76= | Silent (SNP) | VAF 77/129 reads (60%) | catalogued as rs779801661; called by muse, mutect2, varscan2
- SLC7A14 | c.1716C>T p.L572= | Silent (SNP) | VAF 74/295 reads (25%) | catalogued as rs1335392883; called by muse, mutect2, varscan2
- SLC8A1 | c.2664C>T p.I888= | Silent (SNP) | VAF 140/348 reads (40%) | catalogued as rs1003665406, COSV60496005; called by muse, mutect2, varscan2
- SNRPG | c.21C>G p.P7= | Silent (SNP) | VAF 80/284 reads (28%) | called by muse, mutect2, varscan2
- STAB1 | c.5493G>A p.T1831= | Silent (SNP) | VAF 17/220 reads (8%) | catalogued as rs375951164; called by muse, mutect2
- TCFL5 | c.90G>A p.A30= | Silent (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- TERT | c.1995C>T p.L665= | Silent (SNP) | VAF 95/279 reads (34%) | called by muse, mutect2, varscan2
- TEX13C | c.174G>A p.R58= | Silent (SNP) | VAF 103/154 reads (67%) | called by muse, mutect2, varscan2
- TMEM121B | c.342C>G p.S114= | Silent (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- TMEM132D | c.1140C>A p.V380= | Silent (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- TOB1 | c.288A>C p.P96= | Silent (SNP) | VAF 123/378 reads (33%) | called by muse, mutect2, varscan2
- TRIM66 | c.1437C>T p.H479= | Silent (SNP) | VAF 82/134 reads (61%) | called by muse, mutect2, varscan2
- TTN | c.9147C>A p.A3049= (on ENST00000591111; = p.A3003= on NM_003319.4) | Silent (SNP) | VAF 138/253 reads (55%) | called by muse, mutect2, varscan2
- USH1G | c.813G>T p.P271= | Silent (SNP) | VAF 54/88 reads (61%) | catalogued as rs751974726, COSV100140534; called by muse, mutect2, varscan2
- VPS35 | c.1482C>T p.F494= | Silent (SNP) | VAF 196/514 reads (38%) | called by muse, mutect2, varscan2
- WDR47 | c.2001G>T p.V667= (on ENST00000369962 / NM_001142551.2; = p.V668= on NM_014969.5) | Silent (SNP) | VAF 28/112 reads (25%) | called by muse, mutect2, varscan2
- WFDC8 | c.369C>T p.F123= | Silent (SNP) | VAF 127/419 reads (30%) | catalogued as rs773995186; called by muse, mutect2, varscan2
- ZC3H12B | c.2421C>T p.I807= | Silent (SNP) | VAF 76/254 reads (30%) | catalogued as rs776883982, COSV59047278; called by muse, mutect2, varscan2
- ZNF468 | c.621A>G p.E207= | Silent (SNP) | VAF 191/269 reads (71%) | called by muse, mutect2, varscan2
- ABCC3 | c.-7C>A | 5'UTR (SNP) | VAF 37/72 reads (51%) | called by muse, mutect2, varscan2
- AC004522.2 | n.21G>T | RNA (SNP) | VAF 72/318 reads (23%) | called by muse, mutect2, varscan2
- AC006288.1 | n.202C>G | RNA (SNP) | VAF 44/110 reads (40%) | called by muse, mutect2
- AC011840.1 | n.1151C>A | RNA (SNP) | VAF 24/37 reads (65%) | called by muse, mutect2, varscan2
- AC025048.6 | n.141C>G | RNA (SNP) | VAF 84/262 reads (32%) | called by muse, mutect2, varscan2
- AC093642.3 | n.2658C>T | RNA (SNP) | VAF 213/362 reads (59%) | called by mutect2, varscan2
- AC114490.3 | c.*430G>T | 3'UTR (SNP) | VAF 27/78 reads (35%) | called by muse, mutect2, varscan2
- ACTG2 | c.255+216C>A | Intron (SNP) | VAF 61/288 reads (21%) | called by muse, mutect2, varscan2
- ADAM6 | n.1329G>T | RNA (SNP) | VAF 170/725 reads (23%) | called by muse, mutect2, varscan2
- ADGB | c.4818+5513G>T | Intron (SNP) | VAF 146/550 reads (27%) | called by muse, mutect2, varscan2
- AGL | c.83-32G>T | Intron (SNP) | VAF 90/297 reads (30%) | called by muse, mutect2, varscan2
- AL163540.1 | n.306C>A | RNA (SNP) | VAF 42/133 reads (32%) | called by muse, mutect2, varscan2
- AMN | c.44-9C>G | Intron (SNP) | VAF 118/513 reads (23%) | catalogued as rs1425023382; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498808 G>C | 5'Flank (SNP) | VAF 79/251 reads (31%) | catalogued as rs757754929; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499628 G>A | 5'Flank (SNP) | VAF 46/133 reads (35%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500224 G>C | 5'Flank (SNP) | VAF 63/214 reads (29%) | called by muse, mutect2, varscan2
- ARR3 | c.39+17C>A | Intron (SNP) | VAF 43/160 reads (27%) | called by muse, mutect2, varscan2
- ASH1L | chr1:155563456 G>C | 5'Flank (SNP) | VAF 178/409 reads (44%) | called by muse, mutect2, varscan2
- ASXL1 | c.1719+16_1719+26del | Intron (DEL) | VAF 124/454 reads (27%) | called by mutect2, pindel, varscan2
- ATP6V1B1 | c.*28G>T | 3'UTR (SNP) | VAF 112/250 reads (45%) | called by muse, mutect2, varscan2
- BMERB1 | c.-5C>G | 5'UTR (SNP) | VAF 98/162 reads (60%) | called by muse, mutect2, varscan2
- C10orf71 | c.*109_*110insACAA | 3'UTR (INS) | VAF 22/70 reads (31%) | catalogued as COSV60504011, COSV60504447, COSV60505190, COSV60507928, COSV60510659; called by pindel, varscan2
- C5orf60 | n.1625C>T | RNA (SNP) | VAF 209/331 reads (63%) | catalogued as rs943930827, COSV101495112; called by muse, mutect2, varscan2
- CACNB1 | c.-2C>G | 5'UTR (SNP) | VAF 62/110 reads (56%) | called by muse, mutect2, varscan2
- CCL3L3 | c.76+282G>A | Intron (SNP) | VAF 157/248 reads (63%) | called by muse, mutect2, varscan2
- CNOT2 | c.48+15952C>G | Intron (SNP) | VAF 86/248 reads (35%) | called by muse, mutect2, varscan2
- CRTAC1 | c.1819+490G>A | Intron (SNP) | VAF 76/125 reads (61%) | called by muse, mutect2, varscan2
- CSF2RA | c.*129C>A | 3'UTR (SNP) | VAF 97/273 reads (36%) | called by muse, mutect2, varscan2
- CTSL3P | n.311A>T | RNA (SNP) | VAF 101/159 reads (64%) | called by muse, mutect2, varscan2
- CYP11A1 | c.270-38C>T | Intron (SNP) | VAF 34/96 reads (35%) | catalogued as rs760243643; called by muse, mutect2
- DISP2 | c.*304T>C | 3'UTR (SNP) | VAF 84/180 reads (47%) | called by muse, mutect2, varscan2
- DNAH6 | c.7677+22A>T | Intron (SNP) | VAF 90/314 reads (29%) | called by muse, mutect2, varscan2
- DNAJC4 | c.-452G>A | 5'UTR (SNP) | VAF 85/200 reads (43%) | called by muse, mutect2, varscan2
- ERICH3 | c.603+1607C>T | Intron (SNP) | VAF 26/110 reads (24%) | called by muse, mutect2, varscan2
- EYS | c.1767-6676C>A | Intron (SNP) | VAF 185/888 reads (21%) | catalogued as rs761070216; called by muse, mutect2, varscan2
- FAM161A | c.*754C>T | 3'UTR (SNP) | VAF 7/24 reads (29%) | catalogued as rs1454906896; called by muse, mutect2, varscan2
- FANCA | c.1826+411G>T | Intron (SNP) | VAF 55/82 reads (67%) | called by muse, mutect2, varscan2
- FBRS | chr16:30662460 C>T | 5'Flank (SNP) | VAF 99/165 reads (60%) | called by muse, mutect2, varscan2
- FES | c.213+19C>T | Intron (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- FGF14 | c.608-31G>T | Intron (SNP) | VAF 116/384 reads (30%) | called by muse, mutect2, varscan2
- FMO6P | n.1299G>A | RNA (SNP) | VAF 41/90 reads (46%) | called by muse, mutect2, varscan2
- GNG7 | c.-78+3458A>T | Intron (SNP) | VAF 37/60 reads (62%) | called by muse, varscan2
- GNG7 | c.-78+3164G>A | Intron (SNP) | VAF 156/250 reads (62%) | called by muse, mutect2, varscan2
- GPS1 | c.-9G>T | 5'UTR (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2
- GPS1 | c.-7G>T | 5'UTR (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2
- GTF2A1L | chr2:48617846 G>T | 5'Flank (SNP) | VAF 76/268 reads (28%) | called by muse, mutect2
- GVINP1 | n.3174C>A | RNA (SNP) | VAF 89/158 reads (56%) | called by muse, mutect2, varscan2
- GYG1 | c.-77C>G | 5'UTR (SNP) | VAF 481/585 reads (82%) | called by muse, mutect2, varscan2
- HAS2 | c.*86C>A | 3'UTR (SNP) | VAF 78/191 reads (41%) | called by muse, mutect2, varscan2
- HDLBP | c.3720+30C>A | Intron (SNP) | VAF 142/202 reads (70%) | called by muse, mutect2, varscan2
- HSD17B7P2 | n.229C>T | RNA (SNP) | VAF 237/441 reads (54%) | called by muse, mutect2, varscan2
- HSDL2 | chr9:112380086 T>A | 5'Flank (SNP) | VAF 124/193 reads (64%) | called by muse, mutect2, varscan2
- HSPA14 | c.377-246G>C | Intron (SNP) | VAF 66/134 reads (49%) | called by muse, mutect2, varscan2
- ICOSLG | c.898+138C>T | Intron (SNP) | VAF 104/130 reads (80%) | catalogued as rs1056571075; called by muse, mutect2, varscan2
- IGHV1-24 | c.-3A>G | 5'UTR (SNP) | VAF 85/402 reads (21%) | called by muse, mutect2, varscan2
- KCNH2 | c.1128+1844G>A | Intron (SNP) | VAF 94/140 reads (67%) | called by muse, mutect2, varscan2
- KIAA1958 | c.-80C>T | 5'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- KLHL32 | c.-4G>A | 5'UTR (SNP) | VAF 77/280 reads (28%) | called by muse, mutect2, varscan2
- KRT8P11 | n.254G>T | RNA (SNP) | VAF 152/255 reads (60%) | called by muse, mutect2, varscan2
- KRT8P11 | n.255G>T | RNA (SNP) | VAF 152/255 reads (60%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5081T>A | Intron (SNP) | VAF 245/635 reads (39%) | called by muse, mutect2, varscan2
- METAP1D | c.-12A>T | 5'UTR (SNP) | VAF 41/62 reads (66%) | called by muse, mutect2, varscan2
- MGP | c.95-39G>C | Intron (SNP) | VAF 89/430 reads (21%) | called by muse, mutect2, varscan2
- MIR137 | n.48G>A | RNA (SNP) | VAF 28/109 reads (26%) | called by muse, mutect2, varscan2
- MIR205 | n.11A>T | RNA (SNP) | VAF 74/121 reads (61%) | called by muse, mutect2, varscan2
- MIR99A | n.47G>T | RNA (SNP) | VAF 68/248 reads (27%) | called by muse, mutect2, varscan2
- MLH1 | c.1409+48A>G | Intron (SNP) | VAF 216/283 reads (76%) | catalogued as rs1425645796; called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142671106 A>G | 3'Flank (SNP) | VAF 141/261 reads (54%) | called by muse, mutect2, varscan2
- NPIPB1P | n.1072G>T | RNA (SNP) | VAF 170/473 reads (36%) | called by muse, varscan2
- NPIPB1P | n.301T>A | RNA (SNP) | VAF 85/240 reads (35%) | called by muse, mutect2, varscan2
- OR11H6 | chr14:20229679 C>T | 3'Flank (SNP) | VAF 68/189 reads (36%) | called by muse, mutect2, varscan2
- PDK1 | c.410+456T>C | Intron (SNP) | VAF 89/186 reads (48%) | called by muse, mutect2
- PDK1 | c.410+458G>A | Intron (SNP) | VAF 94/197 reads (48%) | called by muse, mutect2
- PGM3 | c.1540-409G>C | Intron (SNP) | VAF 148/407 reads (36%) | called by muse, mutect2, varscan2
- PNPO | c.363+42G>T | Intron (SNP) | VAF 165/408 reads (40%) | called by muse, mutect2, varscan2
- PPIE | c.*14C>T | 3'UTR (SNP) | VAF 50/153 reads (33%) | called by muse, mutect2, varscan2
- PRR33 | c.*7C>T | 3'UTR (SNP) | VAF 18/31 reads (58%) | called by muse, mutect2, varscan2
- RO60 | chr1:193091562 G>A | 3'Flank (SNP) | VAF 15/34 reads (44%) | catalogued as rs1383986826; called by muse, mutect2, varscan2
- RPGRIP1 | c.1763-27G>T | Intron (SNP) | VAF 102/359 reads (28%) | called by muse, mutect2, varscan2
- RPS6KA1 | c.613+25C>T | Intron (SNP) | VAF 52/90 reads (58%) | catalogued as rs565992649, COSV64809665; called by muse, mutect2, varscan2
- RYR1 | c.10937+26C>G | Intron (SNP) | VAF 821/902 reads (91%) | called by muse, mutect2, varscan2
- SDHAF2 | c.37-806G>A | Intron (SNP) | VAF 57/178 reads (32%) | called by muse, mutect2, varscan2
- SEZ6L2 | c.2489-207G>T | Intron (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- SLCO3A1 | c.646+25117C>G | Intron (SNP) | VAF 21/194 reads (11%) | called by muse, mutect2
- SMARCA4 | c.2505+33C>A | Intron (SNP) | VAF 145/242 reads (60%) | called by muse, mutect2, varscan2
- SNORD114-22 | n.71A>G | RNA (SNP) | VAF 61/270 reads (23%) | catalogued as rs750754778; called by muse, mutect2, varscan2
- SNORD116-16 | n.53G>T | RNA (SNP) | VAF 106/370 reads (29%) | called by muse, mutect2, varscan2
- SYPL1 | c.-29C>G | 5'UTR (SNP) | VAF 136/289 reads (47%) | catalogued as rs754420564; called by muse, mutect2, varscan2
- TBC1D8B | c.1203+40G>T | Intron (SNP) | VAF 43/129 reads (33%) | called by muse, mutect2, varscan2
- TLN2 | c.-36-7093C>G | Intron (SNP) | VAF 105/275 reads (38%) | called by muse, mutect2, varscan2
- TMEM165 | c.-26del | 5'UTR (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- TMEM183B | n.84G>C | RNA (SNP) | VAF 112/513 reads (22%) | called by muse, varscan2
- TNPO2 | c.-13-358C>A | Intron (SNP) | VAF 22/40 reads (55%) | catalogued as rs1290972874, COSV63509647; called by muse, mutect2, varscan2
- TPM3 | c.642+619A>G | Intron (SNP) | VAF 270/817 reads (33%) | called by muse, mutect2, varscan2
- TRIM53AP | n.581G>C | RNA (SNP) | VAF 18/91 reads (20%) | called by mutect2, varscan2
- TTN | c.34265-4478C>A | Intron (SNP) | VAF 108/204 reads (53%) | catalogued as rs527403084; called by muse, mutect2, varscan2
- UBE3D | c.77+2480G>C | Intron (SNP) | VAF 48/162 reads (30%) | called by muse, mutect2, varscan2
- VIM | c.1273+30C>A | Intron (SNP) | VAF 155/293 reads (53%) | called by muse, varscan2
- WASF4P | n.667G>T | RNA (SNP) | VAF 174/449 reads (39%) | called by muse, mutect2, varscan2
- XIST | n.9372G>A | RNA (SNP) | VAF 177/470 reads (38%) | catalogued as rs375872813; called by muse, mutect2, varscan2
- XPOT | c.-9A>G | 5'UTR (SNP) | VAF 74/258 reads (29%) | catalogued as rs759216630; called by muse, mutect2
- XXYLT1 | c.785+34284G>C | Intron (SNP) | VAF 58/345 reads (17%) | called by muse, mutect2, varscan2
